TCGA case TCGA-3B-A9HL — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/aaf93a92-2f93-477d-9ea4-d18ab7d4f258

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 67 years; Vital status: Dead; Days to death: 599 days (1.6 years).

Diagnoses (4)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.1; Tissue or organ of origin: Specified parts of peritoneum; Site of resection or biopsy: Specified parts of peritoneum; Classification of tumor: primary; Age at diagnosis: 67.4 years (24,628 days); Year of diagnosis: 2011; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 10.5; Tumor length measurement: 18; Tumor width measurement: 14.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor depth measurement: 9; Tumor length measurement: 12; Tumor width measurement: 6.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: Yes.
2. Metastasis of diagnosis 1 (Dedifferentiated liposarcoma), site: Lung, NOS. Age at diagnosis: 68.1 years (24,857 days); Days to diagnosis: 229 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 0.4.
3. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 68.1 years (24,857 days); Days to diagnosis: 229 days; Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Additional pathology findings: Well Differentiated.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 19.4; Tumor width measurement: 12.4.
4. Metastasis of diagnosis 1 (Dedifferentiated liposarcoma), site: Liver. Age at diagnosis: 68.1 years (24,857 days); Days to diagnosis: 229 days; Prior treatment: Yes; Tumor focality: Unifocal.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.4; Tumor width measurement: 1.6.

Follow-up (4 entries)
- Day 229 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 229 days.
- Day 229 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 229 days.
- Day 229 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 229 days.
- Days to follow up: 599 days (1.6 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3B-A9HL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 80 mg.
  Slide TCGA-3B-A9HL-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3B-A9HL-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3B-A9HL-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Margin status: Positive; Tumor total necrosis: <10% (focal necrosis); Disease multifocal indicator: No; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: No; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic width: 6; Lesion radiologic depth: 9.
- Drug treatment 1: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 185; Days from index date to pharmaceutical treatment ended: 215; Pharmaceutical therapy drug name: Adriamycin; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 1, Therapy types: Pharmaceutical therapy type: Chemotherapy.
- Drug treatment 2: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 447; Days from index date to pharmaceutical treatment ended: 481; Pharmaceutical therapy drug name: DTIC, Dacarbazine; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment 3: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment ended: 432; Pharmaceutical therapy drug name: Gemcitabine; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment ended: 432; Pharmaceutical therapy drug name: Docetaxel; Pharmaceutical treatment ongoing indicator: No; Treatment best response: Clinical Progressive Disease.
- Drug treatment 5: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 532; Days from index date to pharmaceutical treatment ended: 542; Pharmaceutical therapy drug name: Pazopanib; Pharmaceutical treatment ongoing indicator: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 599 days; disease-specific survival: no event (censored), 599 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 229 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3B-A9HL-01A-11D-A386-01): tumor purity 0.66, ploidy 3.79, whole-genome doublings 1.
